Somatic mutation profile of tumor specimen TCGA-E1-A7YY-01A (aliquot TCGA-E1-A7YY-01A-11D-A34J-08) from TCGA case TCGA-E1-A7YY, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 27.0 years (9,867 days).
Specimen TCGA-E1-A7YY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d19177d9-d5c9-4e65-b56d-17bb9b43e03c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E1-A7YY-10A (Blood Derived Normal), aliquot TCGA-E1-A7YY-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c2c1e5dd-8c98-4a9a-9253-e36393b238d0

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CIC | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 4/48 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1157030312, COSV50547633; called by muse, mutect2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 10/79 reads (13%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PLCG2 | c.2096G>A p.G699D | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100842148; called by muse, mutect2
- RASGRP3 | c.404G>A p.R135K | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.855); catalogued as rs1407565966, COSV101274720, COSV99067128; called by muse, mutect2
- UNC79 | c.7588-1G>T p.X2530_splice (on ENST00000393151 / NM_001346218.2; = p.X2353_splice on NM_020818.5) | Splice Site (SNP) | VAF 10/63 reads (16%) | catalogued as COSV99826735; called by muse, mutect2
- WDR44 | c.2679_2681del p.L894del | In Frame Del (DEL) | VAF 6/61 reads (10%) | called by pindel, varscan2
- ACBD5 | c.1002G>A p.Q334= (on ENST00000375888 / NM_001352568.1; = p.Q325= on NM_145698.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as rs771449723, COSV101022524; called by muse, mutect2, varscan2
- TAOK2 | c.1011C>G p.P337= | Silent (SNP) | VAF 13/178 reads (7%) | catalogued as COSV99664238; called by muse, mutect2
